Gene-level copy-number profile of tumor specimen TCGA-2A-A8VT-01A from TCGA case TCGA-2A-A8VT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 47.5 years (17,365 days).
Specimen TCGA-2A-A8VT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.3b68b168-ae91-4a75-9e1f-df53e98cf63b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2A-A8VT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/46967dbb-be6a-4fe7-8ee1-10fcc9f28b24

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 920; copy number 2: 6,397; copy number 3: 11,186; copy number 4: 35,167; copy number 5: 6,126; copy number 6: 1; copy number 7: 2; copy number 8: 12; copy number 9: 1; copy number 10: 3; copy number 11: 1; copy number 12: 2; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2A-A8VT-01A-11D-A376-01): tumor purity 0.56, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 13 (within-gene range 6–13): AC010983.1.
- chr6:115,633,540–115,643,916, 1 gene, copy number 10 (within-gene range 3–10): LINC02534.
- chr7:62,275,361–62,275,678, 1 gene, copy number 11: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 12: AC139365.2, AC139365.1.
- chr12:91,050,491–91,058,024, 1 gene, copy number 9: KERA.
- chr19:27,638,483–27,646,483, 2 genes, copy number 10: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
